Surgical pathology report (de-identified scan), TCGA case TCGA-14-0740, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0740-01B (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

TCGA-14-0740

Document Type: AP Report
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info: [REDACTED]

* Final Report *

Anatomic Pathology Report

Patient: [REDACTED]

Accession Number: [REDACTED]

Patient Number: [REDACTED]

Date Collected: [REDACTED]

Financial Number: [REDACTED]

Date Received: [REDACTED]

Room/Bed: [REDACTED]

PT: [REDACTED]

Admitting Physician: [REDACTED]

Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT TEMPORAL, BIOPSY:
- GLIOBLASTOMA MULTIFORME.
2. BRAIN, RIGHT TEMPORAL, EXCISION:
- GLIOBLASTOMA MULTIFORME.

SPECIMEN:

1. Right temporal brain lesion, [REDACTED]
2. Right temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Craniotomy for excision of brain tumor.
PREOPERATIVE DIAGNOSIS: Brain tumor.
POSTOPERATIVE DIAGNOSIS: Brain tumor.

[page 2 of 2]
[REDACTED]

AP Report

[REDACTED] - [REDACTED]

* Final Report *

[REDACTED]

GROSS DESCRIPTION:

Received are two specimens. Both are labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative evaluation and labeled as "right temporal brain lesion". The specimen consists of multiple fragments of gelatinous, soft tissue measuring approximately 1.2 x 0.5 x 0.3 cm in aggregate. Touch preparations are performed and a portion of the specimen is frozen for intraoperative evaluation. The remainder of the cryoblock is now submitted in cassette "FS1A", whereas the remainder of the specimen is submitted in cassette "1B".

Specimen #2 is received in formalin labeled with the patient's name, hospital number and as "right temporal brain lesion". The specimen consists of multiple fragments of slightly hemorrhagic, soft, gelatinous tissue measuring approximately 1.5 x 1.0 x 0.4 cm in aggregate. All tissue is entirely submitted in two cassettes labeled "2A" and "2B".

[REDACTED]

INTRAOPERATIVE CONSULTATION:

FS1A: BRAIN, RIGHT TEMPORAL LESION (FROZEN SECTION): GLIOBLASTOMA.

[REDACTED]

TISSUE COMMITTEE CODE:

1

ICD-9 CODES:

191.2

Source: NCI Genomic Data Commons file af28cc83-af2a-4bc9-82df-ef448886f8a6 (TCGA-14-0740.909215BA-8F90-4EC1-BCC6-11C75548F3F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).